Somatic mutation profile of tumor specimen TCGA-EM-A3FM-01A (aliquot TCGA-EM-A3FM-01A-11D-A21A-08) from TCGA case TCGA-EM-A3FM, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 57.3 years (20,938 days).
Specimen TCGA-EM-A3FM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b95932e-2346-4a76-bfab-2f71429e1497.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3FM-10A (Blood Derived Normal), aliquot TCGA-EM-A3FM-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d803020-5d64-4856-8b0a-15aaaac4b784

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADAMTS15 | c.1631C>G p.T544S | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV54505458; called by muse, mutect2
- ADARB2 | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.494); catalogued as rs751820473, COSV67182195; called by mutect2, varscan2
- FRMD4A | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as rs772563228, COSV52717882; called by muse, mutect2, varscan2
- MAPK4 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV68542178; called by muse, mutect2
- NUP214 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV63909563; called by muse, mutect2
- PALMD | c.281A>G p.K94R | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.063); catalogued as COSV54164426, COSV54164486; called by muse, mutect2, varscan2
- TMEM181 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65563202; called by muse, mutect2, varscan2
- ZNF136 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 30/71 reads (42%) | catalogued as rs773092857, COSV59710816; called by muse, varscan2
- DYSF | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.077); called by muse, mutect2
- VN1R5 | c.781G>C p.V261L | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.07); called by muse, mutect2
- AKAP13 | c.6885G>A p.E2295= (on ENST00000394518 / NM_007200.5; = p.E2299= on NM_006738.6) | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs1328039634, COSV63457084; called by muse, varscan2
- SLC15A2 | c.219T>C p.Y73= | Silent (SNP) | VAF 72/161 reads (45%) | catalogued as COSV55197834; called by muse, mutect2, varscan2
